Gene-level copy-number profile of tumor specimen TCGA-76-4926-01B from TCGA case TCGA-76-4926, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 68.7 years (25,085 days).
Specimen TCGA-76-4926-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.1a67c896-a819-4662-a297-959dcfc40b05.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-76-4926-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f1f65a4f-4883-4184-8705-b067709584da

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 164; copy number 1: 2; copy number 2: 4,738; copy number 3: 1,376; copy number 4: 50,493; copy number 5: 69; copy number 6: 2,938; copy number 8: 7; copy number 31: 1; copy number 34: 2; copy number 57: 7; copy number 59: 14; copy number 67: 9.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-76-4926-01B-01D-1479-01): tumor purity 0.79, ploidy 1.99, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 116 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:19,507,452–22,455,740, 73 genes (within-gene range 0–1) (broad region; genes not listed).
- chr10:86,756,601–87,553,461, 35 genes (within-gene range 0–2): BMPR1A, RPAP2P1, RNU1-19P, MMRN2, AC025268.1, SNCG, ADIRF-AS1, ADIRF, AL136982.7, AGAP11, BMS1P3, AL136982.1, AL136982.6, AL136982.4, AL136982.2, FAM25A, AL136982.5, RNU6-529P, GLUD1, SHLD2, AL136982.3, RN7SL733P, NUTM2A-AS1, AL157893.2, AL157893.1, NUTM2A, LINC00863, NUTM2D, NPAP1P3, CTSLP1, FAM245A, AL355334.1, AL355334.2, MIR4678, MINPP1.
- chr10:87,751,512–87,994,695, 8 genes (within-gene range 0–2): ATAD1, CFL1P1, RN7SL78P, KLLN, PTEN, AC063965.2, RPL11P3, AC063965.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 33 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:53,316,149–55,572,988, 33 genes, copy number 31–67 (within-gene range 8–67): RNF138P2, RNU1-14P, RN7SKP218, AC009468.2, AC009468.1, LINC01446, RNU2-29P, RAC1P9, AC074348.1, HAUS6P3, LINC02854, AC092848.2, AC092848.1, LINC01445, SLC25A5P3, VSTM2A, VSTM2A-OT1, AC011228.1, RNU6-1125P, RPL31P35, AC011228.3, AC011228.2, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1, LANCL2, VOPP1.

Autosomal genes at a single copy (total copy number 1): 2. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
